Somatic mutation profile of tumor specimen TCGA-76-6660-01A (aliquot TCGA-76-6660-01A-11D-1845-08) from TCGA case TCGA-76-6660, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.7 years (26,913 days).
Specimen TCGA-76-6660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45368f1a-16e6-4097-b05e-f98a8667bccd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6660-10A (Blood Derived Normal), aliquot TCGA-76-6660-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78333a0f-2bd0-4d4f-b726-2dfa75fcc9de

The open-access MAF lists 91 somatic variants for this specimen: 63 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 24, Nonsense Mutation 5, Frame Shift Del 3, Intron 3, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 45/58 reads (78%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); catalogued as rs886041877, CM142089, COSV64294406, COSV64304704; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC26A3 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 51/138 reads (37%) | catalogued as rs1018933248, COSV60641463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.515T>G p.V172G | Missense Mutation (SNP) | VAF 34/62 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1131691021, COSV52683521, COSV52729554, COSV52811339, COSV52993405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3973G>T p.G1325C | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99719650; called by muse, mutect2, varscan2
- ARL6 | c.136A>T p.N46Y | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.439); catalogued as COSV100256522; called by muse, mutect2, varscan2
- AURKA | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.046); catalogued as rs6069717, COSV53860460; called by muse, mutect2, varscan2
- CCDC190 | c.177G>T p.R59S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV63362964; called by muse, mutect2, varscan2
- CEMIP2 | c.3079C>T p.Q1027* | Nonsense Mutation (SNP) | VAF 66/121 reads (55%) | catalogued as COSV100987127; called by muse, mutect2, varscan2
- CHRM1 | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV100186232; called by muse, mutect2
- CNTN4 | c.1907C>T p.T636I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100639410; called by muse, mutect2, varscan2
- CSMD3 | c.10291G>C p.G3431R (on ENST00000297405 / NM_001363185.1; = p.G3262R on NM_052900.3) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52118896, COSV99838380; called by muse, mutect2, varscan2
- CTSG | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs1273091559, COSV53535447, COSV53536639; called by muse, mutect2, varscan2
- CYB5R1 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1393692357, COSV100924848; called by muse, mutect2, varscan2
- DDX5 | c.21C>G p.D7E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99858064; called by muse, mutect2, varscan2
- EDIL3 | c.540C>A p.H180Q | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV56891481, COSV99677419; called by muse, mutect2
- EIF4H | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.341); catalogued as COSV99733569; called by muse, mutect2, varscan2
- FAAP20 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV101052028; called by muse, mutect2, varscan2
- FOXP2 | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100646686, COSV100646966; called by mutect2, varscan2
- GLT8D2 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781621412, COSV100674073; called by muse, mutect2, varscan2
- GRAMD1B | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100454135, COSV100454891; called by muse, mutect2, varscan2
- H3-5 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV61188309; called by muse, mutect2, varscan2
- IGSF3 | c.1798C>T p.R600W (on ENST00000369486 / NM_001007237.3; = p.R620W on NM_001542.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751185422, COSV100604877; called by muse, mutect2, varscan2
- IKZF1 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV100498523; called by muse, mutect2, varscan2
- IMPDH1 | c.1436G>A p.R479Q (on ENST00000470772 / NM_001142573.2; = p.R565Q on NM_000883.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.745); catalogued as COSV58315166; called by muse, mutect2
- KCNB2 | c.1514A>T p.N505I | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.894); catalogued as COSV101578857; called by muse, mutect2, varscan2
- LAMA1 | c.8069T>A p.L2690H | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99072068; called by muse, mutect2, varscan2
- LIPF | c.239T>A p.V80E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99490383; called by muse, varscan2
- MINAR1 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs200499208, COSV59580868; called by muse, mutect2, varscan2
- MUC17 | c.8629A>G p.S2877G | Missense Mutation (SNP) | VAF 105/645 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV60280990; called by muse, mutect2, varscan2
- MYH8 | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV101238480, COSV101238912; called by muse, mutect2, varscan2
- NEDD4 | c.1507A>C p.S503R | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100163862; called by muse, mutect2, varscan2
- OPRD1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as rs139895939; called by muse, mutect2, varscan2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 77/120 reads (64%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OVCH1 | c.1361A>G p.E454G | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs888838126, COSV100548808; called by muse, mutect2, varscan2
- PALLD | c.3217C>T p.R1073* (on ENST00000505667 / NM_001166108.2; = p.R1056* on NM_016081.4) | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as COSV99825088; called by muse, mutect2, varscan2
- PEG3 | c.4532C>G p.T1511R | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as rs1216979385, COSV55652711, COSV99689448; called by muse, mutect2, varscan2
- PPP1R3A | c.126T>G p.S42R | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99493322; called by muse, mutect2
- PRPF4 | c.122G>A p.R41H (on ENST00000374198 / NM_001322267.2; = p.R42H on NM_004697.5) | Missense Mutation (SNP) | VAF 160/273 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs1299420214, COSV100950717; called by muse, mutect2, varscan2
- REV1 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1420025386, COSV99301123; called by muse, mutect2, varscan2
- RIT2 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56300359; called by muse, mutect2, varscan2
- RNF141 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); catalogued as rs752292152, COSV99792937; called by muse, mutect2, varscan2
- RPS6KA2 | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99691337; called by muse, mutect2, varscan2
- SLC18A3 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100340376; called by muse, mutect2, varscan2
- SMYD3 | c.778G>T p.E260* (on ENST00000490107 / NM_001375962.1; = p.E201* on NM_022743.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/102 reads (55%) | catalogued as COSV100830790; called by muse, mutect2, varscan2
- SPART | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100768790; called by muse, mutect2
- SPEN | c.8257G>A p.V2753I | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV101005343; called by muse, mutect2, varscan2
- STIP1 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 57/152 reads (38%) | catalogued as COSV59441626; called by muse, mutect2, varscan2
- TACC3 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs1374170639, COSV100508821; called by muse, mutect2, varscan2
- TGM7 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.869); catalogued as rs369585501; called by muse, mutect2, varscan2
- TPO | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs775202863, COSV61097383; called by muse, mutect2, varscan2
- TPST2 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100114157; called by muse, mutect2
- TTN | c.53428C>T p.R17810C (on ENST00000591111; = p.R10386C on NM_003319.4) | Missense Mutation (SNP) | VAF 80/187 reads (43%) | PolyPhen probably damaging (0.998); catalogued as rs763871350, COSV59871749; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VTCN1 | c.806G>T p.S269I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs756445973, COSV100061942; called by muse, mutect2, varscan2
- WDR36 | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV101550985; called by muse, mutect2, varscan2
- WDR75 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV100134310; called by muse, mutect2, varscan2
- WWC3 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 59/65 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs758458102, COSV101081559; called by muse, mutect2, varscan2
- XYLT2 | c.1973T>C p.L658P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99190997; called by muse, mutect2, varscan2
- ZNF883 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172196545, COSV101432626; called by muse, varscan2
- ZNF883 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 118/218 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs369861735; called by muse, varscan2
- BCL2 | c.649_650del p.L217Efs*38 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | called by pindel, varscan2
- CCDC141 | c.2902del p.T968Pfs*6 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | called by mutect2, pindel, varscan2
- CHD9 | c.6113_6121del p.K2038_I2040del | In Frame Del (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- ZNF433 | c.1126del p.Y376Ifs*295 | Frame Shift Del (DEL) | VAF 29/103 reads (28%) | called by mutect2, pindel, varscan2
- AHI1 | c.2628A>G p.E876= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as COSV99663047; called by muse, mutect2, varscan2
- ARHGAP5 | c.459G>A p.K153= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as rs374638293; called by muse, mutect2, varscan2
- ATP8B4 | c.1386C>A p.P462= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV99462766; called by muse, mutect2, varscan2
- BCKDHB | c.312T>C p.F104= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as rs745368116, COSV100243758; called by muse, mutect2, varscan2
- CNTNAP5 | c.2703G>A p.S901= | Silent (SNP) | VAF 80/190 reads (42%) | catalogued as rs536438687, COSV101443740; called by muse, mutect2, varscan2
- DCLK1 | c.669C>T p.A223= | Silent (SNP) | VAF 62/140 reads (44%) | catalogued as rs1265531242, COSV99711850; called by muse, mutect2, varscan2
- DMBT1 | c.6582A>G p.E2194= (on ENST00000338354 / NM_001377530.1; = p.E1437= on NM_004406.3) | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100353372; called by muse, mutect2, varscan2
- DNM2 | c.498G>A p.R166= | Silent (SNP) | VAF 50/186 reads (27%) | catalogued as COSV100117471; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.765C>T p.A255= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as rs753769067, COSV100374517; called by muse, mutect2, varscan2
- GPR20 | c.966C>T p.S322= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as rs777324865, COSV100897342; called by muse, mutect2, varscan2
- IGSF1 | c.3300G>A p.K1100= | Silent (SNP) | VAF 226/251 reads (90%) | catalogued as COSV63838128; called by muse, mutect2, varscan2
- KCNT1 | c.1581G>A p.P527= (on ENST00000488444; = p.P546= on NM_020822.3) | Silent (SNP) | VAF 55/81 reads (68%) | catalogued as rs138352399; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEC1 | c.2754T>C p.F918= | Silent (SNP) | VAF 237/269 reads (88%) | catalogued as COSV99595993; called by muse, mutect2, varscan2
- N4BP3 | c.822C>T p.G274= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs966566936, COSV99200717; called by muse, mutect2, varscan2
- NLRP14 | c.2946A>G p.R982= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV100205179; called by muse, mutect2, varscan2
- NPHP3 | c.987C>T p.C329= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs138124482; called by muse, mutect2, varscan2
- PKN3 | c.2394G>A p.P798= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs1201562878, COSV99403722; called by muse, mutect2, varscan2
- PTGDR | c.804G>A p.A268= | Silent (SNP) | VAF 37/295 reads (13%) | catalogued as COSV100035646; called by muse, mutect2, varscan2
- RNF43 | c.240A>G p.G80= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV100090400; called by muse, mutect2, varscan2
- ROBO1 | c.3390C>T p.D1130= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV101458918; called by muse, mutect2, varscan2
- RUBCN | c.324C>T p.N108= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs1393526467, COSV99584397; called by muse, mutect2, varscan2
- SEPTIN14 | c.228C>T p.N76= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV101193376; called by muse, mutect2, varscan2
- SLIT2 | c.3234C>T p.D1078= | Silent (SNP) | VAF 88/225 reads (39%) | catalogued as rs573018203, COSV56560099; called by muse, mutect2, varscan2
- WT1 | c.1051A>C p.R351= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as CM041491, COSV100188368; called by muse, mutect2, varscan2
- CALCR | c.51+2978C>T | Intron (SNP) | VAF 48/157 reads (31%) | catalogued as rs774519762, COSV64005791, COSV64008954; called by muse, mutect2, varscan2
- MICAL3 | c.2241+4630C>T | Intron (SNP) | VAF 77/177 reads (44%) | catalogued as rs774369417, COSV52908665; called by muse, mutect2, varscan2
- MIR522 | n.78C>T | RNA (SNP) | VAF 52/109 reads (48%) | catalogued as rs781379833; called by muse, mutect2, varscan2
- THSD4 | c.1016-70219C>T | Intron (SNP) | VAF 71/174 reads (41%) | catalogued as rs781754160; called by muse, mutect2, varscan2
